Somatic mutation profile of tumor specimen 0DSWZ9 from CCDI case PBCIWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Epithelial-myoepithelial carcinoma; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 16.3 years (5,949 days).
Specimen 0DSWZ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca064e1f-e00d-4551-a61c-6507f6c874c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWZ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee81ca6f-973b-4305-9834-c0ca712b4429

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1376_1378del p.K459del (on ENST00000521381 / NM_181523.3; = p.K189del on NM_181504.4) | In Frame Del (DEL) | VAF 100/824 reads (12%) | hotspot (GDC flag); called by mutect2, varscan2
- ABTB2 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as rs1285236376; called by muse, mutect2
- KCNG2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs748713635, COSV60270617; called by muse, mutect2, varscan2
- AHNAK | c.8591T>A p.L2864Q | Missense Mutation (SNP) | VAF 27/788 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- ZNF473 | c.1081C>A p.H361N | Missense Mutation (SNP) | VAF 36/898 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.55); called by muse, mutect2
